MMRF case MMRF_1352 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/8cc7a02b-2714-40d2-a700-2aca6d715032

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 54 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 54.1 years (19,752 days); ISS stage: I; Days to last known disease status: 1,381 days (3.8 years); Days to last follow up: 1,381 days (3.8 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 218 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 233 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 190 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 190 days; Days to treatment end: 218 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 267 days; Days to treatment end: 267 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 267 days; Days to treatment end: 267 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 374 days (1.0 years); Days to treatment end: 1,102 days (3.0 years).
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1,102 days (3.0 years); Days to treatment end: 1,515 days (4.1 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -6 (ECOG 0): M Protein 1.83 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.51 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.084 mg/dL; Immunoglobulin G 3.41 g/L; Immunoglobulin A 20.5 g/L; Immunoglobulin M 0.11 g/L; Beta 2 Microglobulin 2.53 µg/mL; Lactate Dehydrogenase 2.12 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 129 ×10⁹/L; Creatinine 99.9 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.33 mmol/L; Albumin 41 g/L; Total Protein 7.9 g/dL; Glucose 5.34 mmol/L; C-Reactive Protein 0.03 mg/dL.
- Day 87 (ECOG 0): M Protein 0.91 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.46 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.079 mg/dL; Immunoglobulin G 3.04 g/L; Immunoglobulin A 11.8 g/L; Immunoglobulin M 0.14 g/L; Lactate Dehydrogenase 3 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 118 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.33 mmol/L; Albumin 39 g/L; Total Protein 6.5 g/dL; Glucose 4.51 mmol/L.
- Day 178 (ECOG 0): M Protein 0.59 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.594 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.108 mg/dL; Immunoglobulin G 2.97 g/L; Immunoglobulin A 6.5 g/L; Immunoglobulin M 0.11 g/L; Lactate Dehydrogenase 2.63 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 136 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.28 mmol/L; Albumin 45 g/L; Total Protein 6.9 g/dL; Glucose 6.44 mmol/L.
- Day 263 (ECOG 0): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.439 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.089 mg/dL; Immunoglobulin G 3.14 g/L; Immunoglobulin A 7.76 g/L; Immunoglobulin M 0.12 g/L; Beta 2 Microglobulin 1.53 µg/mL; Lactate Dehydrogenase 2.62 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 180 ×10⁹/L; Creatinine 86.6 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.23 mmol/L; Albumin 47 g/L; Total Protein 7.1 g/dL; Glucose 5.01 mmol/L.
- Day 367 (ECOG 0): M Protein 0.24 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.446 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.519 mg/dL; Immunoglobulin G 4.46 g/L; Immunoglobulin A 3.55 g/L; Immunoglobulin M 0.38 g/L; Lactate Dehydrogenase 3.02 µkat/L; Hemoglobin 9.61 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 171 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.48 mmol/L; Albumin 46 g/L; Total Protein 7.3 g/dL; Glucose 5.34 mmol/L.
- Day 486 (ECOG 0): M Protein 0.19 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.555 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.787 mg/dL; Immunoglobulin G 4.65 g/L; Immunoglobulin A 3.07 g/L; Immunoglobulin M 0.22 g/L; Lactate Dehydrogenase 2.9 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 128 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.25 mmol/L; Albumin 40 g/L; Total Protein 6.6 g/dL; Glucose 5.28 mmol/L.
- Day 548 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.527 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.826 mg/dL; Immunoglobulin G 4.22 g/L; Immunoglobulin A 2.73 g/L; Immunoglobulin M 0.15 g/L; Beta 2 Microglobulin 1.4 µg/mL; Lactate Dehydrogenase 2.58 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 122 ×10⁹/L; Creatinine 89.3 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.23 mmol/L; Albumin 40 g/L; Total Protein 6.3 g/dL; Glucose 5.34 mmol/L.
- Day 611 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.659 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.764 mg/dL; Immunoglobulin G 5.01 g/L; Immunoglobulin A 3.2 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 2.32 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 110 ×10⁹/L; Creatinine 91.9 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 6.3 g/dL; Glucose 5.17 mmol/L.
- Day 702: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.12 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.651 mg/dL; Immunoglobulin G 4.21 g/L; Immunoglobulin A 2.97 g/L; Immunoglobulin M 0.23 g/L; Lactate Dehydrogenase 2.05 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 90 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.18 mmol/L; Albumin 39 g/L; Total Protein 6.1 g/dL; Glucose 4.68 mmol/L.
- Day 807: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.648 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.8 mg/dL; Immunoglobulin G 4.6 g/L; Immunoglobulin A 3.08 g/L; Immunoglobulin M 0.14 g/L; Beta 2 Microglobulin 1.14 µg/mL; Lactate Dehydrogenase 1.83 µkat/L; Hemoglobin 9.05 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.36 ×10⁹/L; Platelets 103 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.2 mmol/L; Albumin 40 g/L; Total Protein 6.5 g/dL; Glucose 5.17 mmol/L.
- Day 892 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.67 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.14 mg/dL; Immunoglobulin G 5.59 g/L; Immunoglobulin A 1.18 g/L; Immunoglobulin M 0.23 g/L; Lactate Dehydrogenase 2.6 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 156 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.2 mmol/L; Albumin 36 g/L; Total Protein 5.8 g/dL; Glucose 5.39 mmol/L.
- Day 939 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.794 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.06 mg/dL; Immunoglobulin G 4.65 g/L; Immunoglobulin A 2.77 g/L; Immunoglobulin M 0.15 g/L; Beta 2 Microglobulin 1.43 µg/mL; Lactate Dehydrogenase 1.78 µkat/L; Hemoglobin 8.99 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 103 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.2 mmol/L; Albumin 39 g/L; Total Protein 6.3 g/dL; Glucose 4.84 mmol/L.
- Day 1,047 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.12 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.01 mg/dL; Immunoglobulin G 5.08 g/L; Immunoglobulin A 3.18 g/L; Immunoglobulin M 0.22 g/L; Lactate Dehydrogenase 2.2 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 101 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.23 mmol/L; Albumin 41 g/L; Total Protein 6.4 g/dL; Glucose 5.06 mmol/L.
- Day 1,102 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.922 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.08 mg/dL; Immunoglobulin G 5.73 g/L; Immunoglobulin A 3.23 g/L; Immunoglobulin M 0.14 g/L; Beta 2 Microglobulin 1.44 µg/mL; Lactate Dehydrogenase 2.72 µkat/L; Hemoglobin 8.93 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 144 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.4 mmol/L; Albumin 42 g/L; Total Protein 6.3 g/dL; Glucose 4.79 mmol/L.
- Day 1,263: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.01 mg/dL; Immunoglobulin G 5.96 g/L; Immunoglobulin A 3.3 g/L; Immunoglobulin M 0.74 g/L; Lactate Dehydrogenase 2.48 µkat/L; Hemoglobin 8.99 mmol/L; Leukocytes 2.5 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 131 ×10⁹/L; Creatinine 96.4 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.23 mmol/L; Albumin 39 g/L; Total Protein 6 g/dL; Glucose 5.5 mmol/L.
- Day 1,290: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.33 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.02 mg/dL; Immunoglobulin G 5.55 g/L; Immunoglobulin A 3.12 g/L; Immunoglobulin M 0.16 g/L; Lactate Dehydrogenase 2.17 µkat/L; Hemoglobin 8.87 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 111 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.23 mmol/L; Albumin 39.6 g/L; Total Protein 5.5 g/dL; Glucose 5.45 mmol/L.
- Day 1,381 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.02 mg/dL; Immunoglobulin G 6.03 g/L; Immunoglobulin A 3.34 g/L; Immunoglobulin M 0.16 g/L; Lactate Dehydrogenase 2.3 µkat/L; Hemoglobin 8.8 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 104 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.33 mmol/L; Albumin 42 g/L; Total Protein 6.8 g/dL; Glucose 5.39 mmol/L.

Other clinical attributes
- Day -6: Weight: 102 kg; Height: 185 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Breast Cancer; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Father; Relationship sex at birth: male.

Biospecimens (3 samples)
- Sample MMRF_1352_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -6 days.
- Sample MMRF_1352_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -6 days.
- Sample MMRF_1352_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 367 days (1.0 years).
